Somatic mutation profile of tumor specimen TCGA-V1-A9O5-06A (aliquot TCGA-V1-A9O5-06A-11D-A41K-08) from TCGA case TCGA-V1-A9O5, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9O5-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1182b056-37a1-4fb1-bd4a-280d7d21a68f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9O5-10A (Blood Derived Normal), aliquot TCGA-V1-A9O5-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9423dc25-ee8e-44fa-85cc-02806cd7bc80

The open-access MAF lists 39 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, Frame Shift Del 3, In Frame Del 2, Nonsense Mutation 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.449del p.F150Sfs*15 | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | catalogued as rs1567817974; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.715A>G p.N239D | Missense Mutation (SNP) | VAF 20/39 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs876660807, COSV52664075, COSV52685174, COSV52979974, COSV53345856; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AHSA1 | c.354+1G>C p.X118_splice | Splice Site (SNP) | VAF 9/53 reads (17%) | catalogued as COSV99375914; called by muse, mutect2, varscan2
- ASAP1 | c.216G>C p.Q72H | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as rs1180851532, COSV100727049; called by muse, mutect2, varscan2
- C19orf54 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.461); catalogued as rs1381088908, COSV99648579; called by muse, mutect2, varscan2
- C8orf74 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.58); PolyPhen benign (0.09); catalogued as rs374082262; called by muse, mutect2, varscan2
- CPT1A | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV99680880; called by muse, mutect2, varscan2
- CSMD3 | c.9943T>C p.F3315L (on ENST00000297405 / NM_001363185.1; = p.F3146L on NM_052900.3) | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1563694586, COSV99830114; called by muse, mutect2, varscan2
- FLG | c.8110A>G p.T2704A | Missense Mutation (SNP) | VAF 64/359 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as COSV100912399; called by muse, mutect2, varscan2
- ICAM1 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs763975382, COSV99320665; called by muse, mutect2, varscan2
- IPO4 | c.2746C>T p.R916* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as rs767458231, COSV61016611; called by muse, mutect2, varscan2
- LPP | c.1299G>A p.M433I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV57079696; called by muse, mutect2, varscan2
- NAT2 | c.156A>T p.L52F | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV99674023; called by muse, mutect2, varscan2
- NDNF | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs151063601; called by muse, mutect2, varscan2
- OSCAR | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99499895; called by muse, mutect2, varscan2
- PAPPA2 | c.2021A>G p.E674G | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100866693; called by muse, mutect2, varscan2
- PHC1 | c.1958C>G p.S653C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as COSV101418551; called by muse, mutect2, varscan2
- PKHD1L1 | c.4670T>A p.L1557Q | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV101005829; called by muse, mutect2, varscan2
- PLIN4 | c.1936G>A p.A646T (on ENST00000301286; = p.A661T on NM_001367868.2) | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.157); catalogued as rs770863550, COSV56687875; called by muse, mutect2, varscan2
- PYHIN1 | c.1429C>A p.P477T | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); catalogued as COSV100932543, COSV100932595, COSV63732699; called by muse, mutect2, varscan2
- RBM4 | c.169C>A p.H57N | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.425); catalogued as COSV100029584; called by muse, mutect2, varscan2
- SCRIB | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.077); catalogued as rs1331834002, COSV100252910; called by muse, mutect2
- STRN3 | c.2374C>A p.L792I (on ENST00000357479 / NM_001083893.2; = p.L708I on NM_014574.4) | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100670473; called by muse, mutect2, varscan2
- TTC7B | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.041); catalogued as rs538272204, COSV60626174; called by muse, mutect2, varscan2
- UBQLNL | c.1173G>T p.Q391H | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV100974192; called by muse, mutect2, varscan2
- WNK3 | c.2774A>G p.N925S | Missense Mutation (SNP) | VAF 97/117 reads (83%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV100671092; called by muse, mutect2, varscan2
- ABCA13 | c.9719del p.G3240Vfs*6 | Frame Shift Del (DEL) | VAF 19/41 reads (46%) | called by mutect2, pindel, varscan2
- CACNA1G | c.6733_6735del p.K2245del | In Frame Del (DEL) | VAF 12/32 reads (38%) | called by pindel, varscan2
- RERE | c.1246_1248del p.F416del | In Frame Del (DEL) | VAF 16/76 reads (21%) | called by pindel, varscan2
- TRAPPC8 | c.423del p.L142* | Frame Shift Del (DEL) | VAF 20/101 reads (20%) | called by mutect2, pindel, varscan2
- APC | c.2946G>A p.S982= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs377384463; ClinVar: likely benign; called by muse, mutect2, varscan2
- CD177 | c.462G>A p.G154= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1256841906, COSV100945901; called by mutect2, varscan2
- DCAF8L1 | c.1752A>G p.S584= | Silent (SNP) | VAF 40/50 reads (80%) | catalogued as COSV101491431; called by muse, mutect2, varscan2
- EPPK1 | c.5499G>A p.T1833= | Silent (SNP) | VAF 214/388 reads (55%) | catalogued as rs1017044924, COSV101599791; called by muse, mutect2, varscan2
- FCGBP | c.5481C>T p.V1827= | Silent (SNP) | VAF 126/379 reads (33%) | catalogued as rs1156822716; called by muse, mutect2, varscan2
- HPS3 | c.2037C>T p.T679= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99937303; called by muse, mutect2, varscan2
- PPP1R1B | c.594C>A p.S198= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99566171; called by mutect2, varscan2
- SYMPK | c.2104C>T p.L702= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99841551; called by muse, mutect2, varscan2
- VRTN | c.*2A>G | 3'UTR (SNP) | VAF 9/23 reads (39%) | catalogued as rs1235339424, COSV99832184; called by muse, mutect2, varscan2
